TCGA case TCGA-BR-6707 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/df3df249-86c2-43d4-abe1-796cd7df653f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Ukraine; Age at index: 75 years; Vital status: Dead; Days to death: 605 days (1.7 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.2; Tissue or organ of origin: Body of stomach; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 75.4 years (27,529 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 15.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Oxaliplatin; Days to treatment start: 426 days (1.2 years); Days to treatment end: 491 days (1.3 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Days to treatment start: 426 days (1.2 years); Days to treatment end: 491 days (1.3 years); Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Adenocarcinoma, NOS). Age at diagnosis: 76.5 years (27,955 days); Days to diagnosis: 426 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS to Locoregional Site.

Follow-up (4 entries)
- Days to follow up: 30 days; Disease response: Tumor Free.
- Day 426 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 426 days (1.2 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 491 days (1.3 years); Disease response: With Tumor.
- Days to follow up: 605 days (1.7 years); Disease response: With Tumor.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BR-6707-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2.3; Intermediate dimension: 2; Shortest dimension: 0.5.
  Slide TCGA-BR-6707-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10.
  Slide TCGA-BR-6707-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 15.
- Sample TCGA-BR-6707-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BR-6707-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Fundus/Body; Lymph nodes examined: Yes; Cancer procurement city: Kiev; Number of relatives with stomach cancer: 0.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Drug treatment 3: Pharmaceutical therapy drug name: 5-Fluorouracil; Treatment best response: Clinical Progressive Disease.
- Follow-up form 1: Lost to follow-up: No; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; Treatment outcome first course: Complete Remission/Response; Cause of death: Stomach Cancer.
- Follow-up form 1, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.
- Follow-up form 1, New neoplasm event types: New tumor event type: Locoregional Recurrence.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 491 days; disease-specific survival: no event (censored), 491 days; disease-free interval: event (new tumor event after initially disease-free), 426 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 426 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BR-6707-01A-11D-1881-01): tumor purity 0.53, ploidy 2.13, whole-genome doublings 0.
